Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5888, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5888-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

year old male with right renal mass.

Specimens Submitted:

1: SP: Right renal tumor (fs)

2: SP: Deep surgical margin, right kidney

3: SP: Paracaval lymph node

DIAGNOSIS:

1. SP: Right renal tumor (fs):

Tumor Type:

Renal cell carcinoma - Unclassified type

High grade. See comment

Tumor Size:

Greatest diameter is 3.7 cm.

This pertains to the largest tumor although multiple lesions are present. See comment

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Tumor present at renal parenchymal margin (for partial nephrectomy specimens only)

See comment

Non-Neoplastic Kidney:

Marked chronic inflammation and arteriolonephrosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

COMMENT: The tumors in this case exhibit a very unusual constellation of features that do not fit into any of our well defined categories. The main tumor mass is predominantly papillary and solid with focal tubular areas. It is high grade. Focal areas of necrosis are evident. In the adjacent renal parenchyma there are innumerable neoplastic foci that have tubular features and basophilic cytoplasm. These measure from 3 millimeters to less than 0.1 millimeter. It is these foci of disease that are present at

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

the parenchymal margin of resection. The main tumor mass is immunoreactive for CK7 and focally for racemase. It is negative for CA9. The satellite nodules are immunoreactive for CK7 but negative for racemase. BAF-47 is not interpretable. The overall appearance is suggestive of a syndrome-associated tumor although the unusual morphology does not allow us to make this statement with confidence or to suggest the syndrome involved, if such is the case. Close examination of the contralateral kidney is advised.

Seen in consultation with [REDACTED]

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments [REDACTED] as qualified to perform high complexity clinical laboratory testing.

2. **SP: Deep surgical margin, right kidney:**
- Benign renal medullary parenchyma.

3. **SP: Paracaval lymph node:**
Lymph Nodes:
Not involved
Number of nodes examined: 2
with focal granulomas

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RACEMASE	
	CK7	
	CA-1X	
	BAF-47	
	NEG CONT	
	IMM RECUT	
	CK7	
	RACEMASE	
	BAF-47	
	IMM RECUT	
	NEG CONT	

Gross Description:

1) The specimen is received fresh for frozen section consultation and is labeled "Right renal tumor". It consists of a 4.5 x 4 x 4 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a tan white tumor with large areas of necrosis, measuring 3.7 x 3.5 x 2.5 cm. The clearance from the resection margin is 0.5 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:
FSC - frozen section control
T - tumor
M - margin
RS - representative sections

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

2). The specimen is received in formalin, labeled "deep surgical margin right kidney" and consists of a 0.7 x 0.6 x 0.2 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:
U - undesignated

3). The specimen is received in formalin labeled "Paracaval lymph node" and consists of two pink tan firm lymph nodes with attached fatty fibrous tissue ranging from 0.3 cm up to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN-lymph node
BLN-bisected lymph node

Summary of Sections:

Part 1: SP: Right renal tumor (fs)

Block	Sect. Site	PCs
5	add	5
1	fsc	1
1	m	1
1	rs	1
5	t	5

Part 2: SP: Deep surgical margin, right kidney

Block	Sect. Site	PCs
1	u	1

Part 3: SP: Paracaval lymph node

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT RENAL TUMOR (FS): LARGELY NECROTIC RENAL TUMOR;
MARGIN NEGATIVE.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 4bb35eb9-41ae-419d-89c3-a56caaafa3f4 (TCGA-BQ-5888.F725DD99-EEE0-4F0A-90BA-4AEEF1E2FC4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).